Somatic mutation profile of tumor specimen TCGA-76-6282-01A (aliquot TCGA-76-6282-01A-11D-1696-08) from TCGA case TCGA-76-6282, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.9 years (23,323 days).
Specimen TCGA-76-6282-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db319a66-90f5-4611-9b25-9e3db86496d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6282-10A (Blood Derived Normal), aliquot TCGA-76-6282-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73fe0425-d669-4f44-b1f5-7724049331d5

The open-access MAF lists 43 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 29, Silent 9, Frame Shift Del 2, Nonsense Mutation 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDR | c.3094C>T p.R1032* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | hotspot (GDC flag); catalogued as rs767542615, COSV55758800; called by muse, mutect2, varscan2
- AADACL3 | c.944T>C p.V315A | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV60199458; called by muse, mutect2, varscan2
- ANO5 | c.2255C>T p.T752M | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373471188, COSV100202342; called by muse, mutect2, varscan2
- BOC | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs149038528, COSV104383250; called by muse, mutect2, varscan2
- CD22 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs756739741, COSV50052460; called by muse, mutect2
- DSC1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV57142904; called by muse, mutect2, varscan2
- EFHB | c.745A>T p.I249L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV55549366; called by muse, mutect2, varscan2
- EGFR | c.1712G>C p.C571S | Missense Mutation (SNP) | VAF 1359/1833 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51810174; called by muse, mutect2, varscan2
- GRIN2A | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778951185, COSV58035660; called by muse, mutect2, varscan2
- HSD17B13 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs778806212, COSV56345570; called by muse, mutect2, varscan2
- ITPR2 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159482369, COSV67270866; called by muse, mutect2, varscan2
- KRT33A | c.262A>C p.I88L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as COSV50368257; called by muse, mutect2, varscan2
- MFSD9 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs757190136, COSV51492557; called by muse, mutect2, varscan2
- MLN | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV56474810; called by muse, mutect2, varscan2
- MS4A12 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV50014717; called by muse, mutect2, varscan2
- MYLIP | c.108C>G p.I36M | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62766955; called by muse, varscan2
- NAIP | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs780390257, COSV52001731, COSV52003338; called by muse, mutect2, varscan2
- OR2A25 | c.578T>C p.I193T | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV68717334; called by muse, mutect2, varscan2
- OR52B4 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs1046263046, COSV68769109; called by muse, mutect2
- OTX2 | c.303G>T p.Q101H (on ENST00000408990 / NM_172337.3; = p.Q109H on NM_021728.4) | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.547); catalogued as COSV59766549; called by muse, mutect2, varscan2
- PTCD2 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs755116275, COSV54651361, COSV54654034, COSV99781895; called by muse, mutect2, varscan2
- RIMS2 | c.2944C>T p.R982* (on ENST00000666250 / NM_001348490.2; = p.R790* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/114 reads (23%) | catalogued as rs201715496, COSV51684946; called by muse, mutect2, varscan2
- RRP1B | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs567364998, COSV61478877, COSV61479292; called by muse, mutect2, varscan2
- SHKBP1 | c.1913A>G p.N638S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV52540804; called by muse, varscan2
- SLC27A2 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV51059817; called by muse, mutect2, varscan2
- SRRM2 | c.3437C>G p.P1146R | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV57075040; called by muse, mutect2, varscan2
- TNFSF9 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs746585700, COSV55538526; called by muse, mutect2, varscan2
- TNXB | c.11593A>G p.T3865A (on ENST00000647633; = p.T3618A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.968); catalogued as COSV64480918, COSV64482167; called by muse, mutect2
- UBE4A | c.2365A>T p.N789Y (on ENST00000252108 / NM_001204077.2; = p.N796Y on NM_004788.4) | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52804789; called by muse, mutect2, varscan2
- VPS41 | c.1449G>T p.W483C | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59649806; called by muse, mutect2
- ZNF536 | c.3133G>T p.A1045S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV62826332; called by muse, mutect2, varscan2
- OTOP2 | c.583del p.Q195Nfs*120 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- SLC5A7 | c.1138del p.V380Lfs*19 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.523A>T p.T175S | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2
- AGAP1 | c.604C>T p.L202= | Silent (SNP) | VAF 52/168 reads (31%) | catalogued as COSV58329398; called by muse, mutect2, varscan2
- FGD5 | c.1476T>C p.Y492= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV53238170, COSV53245130; called by muse, mutect2, varscan2
- MROH9 | c.1263C>T p.P421= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV63011998; called by muse, mutect2, varscan2
- MTUS2 | c.1749G>A p.T583= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs757126872, COSV70917100; called by muse, mutect2, varscan2
- MUC16 | c.32334G>A p.S10778= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as rs779238574, COSV67473766; called by muse, mutect2, varscan2
- MYLIP | c.186C>T p.I62= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs543355473, COSV62766963; called by muse, varscan2
- RGL4 | c.243G>A p.P81= | Silent (SNP) | VAF 55/166 reads (33%) | catalogued as rs141395325; called by muse, mutect2, varscan2
- SRRM2 | c.2448C>T p.R816= | Silent (SNP) | VAF 107/386 reads (28%) | catalogued as COSV57075027, COSV57075659; called by muse, mutect2, varscan2
- VPS18 | c.2028G>A p.P676= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs765867213, COSV55030793; called by muse, mutect2, varscan2
